Gene-level copy-number profile of tumor specimen TCGA-A2-A04W-01A from TCGA case TCGA-A2-A04W, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Apocrine adenocarcinoma; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 50.2 years (18,345 days).
Specimen TCGA-A2-A04W-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.e22edca1-493b-4d79-a311-3d5027d1e509.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A2-A04W-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3691a49d-3a0c-40b3-852d-fdb4f95d63ac

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,150; copy number 2: 13,756; copy number 3: 22,745; copy number 4: 15,555; copy number 5: 4,655; copy number 6: 548; copy number 7: 403; copy number 8: 204; copy number 9: 72; copy number 10: 58; copy number 11: 62; copy number 12: 27; copy number 13: 29; copy number 14: 109; copy number 15: 51; copy number 16: 43; copy number 17: 16; copy number 18: 22; copy number 19: 13; copy number 20: 16; copy number 21: 45; copy number 23: 10; copy number 24: 51; copy number 25: 5; copy number 26: 79; copy number 27: 33; copy number 29: 5; copy number 30: 4; copy number 31: 12; copy number 33: 21; copy number 36: 1; copy number 38: 8; copy number 42: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-A2-A04W-01A-31D-A111-01): tumor purity 0.3, ploidy 3.14, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,320 genes in 36 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:9,148,011–10,982,037, 54 genes, copy number 7 (within-gene range 2–7): MIR34AHG, MIR34A, LNCTAM34A, H6PD, SPSB1, BX323043.1, LINC02606, RNA5SP40, AL928921.1, SLC25A33, AL954705.1, TMEM201, PIK3CD, PIK3CD-AS1, AL691449.1, PIK3CD-AS2, CLSTN1, MZT1P1, AL357140.3, CTNNBIP1, AL357140.1, AL357140.4, LZIC, AL357140.2, NMNAT1, RN7SKP269, TMEM274P, MIR5697, AL603962.1, RBP7, UBE4B, AL590639.1, PGAM1P11, RNU6-828P, KIF1B, AL358013.1, RNU6-37P, RN7SL731P, AL139424.3, AL139424.2, PGD, AL139424.1, CENPS-CORT, CENPS, CORT, DFFA, AL354956.1, PEX14, AL139423.2, RN7SL614P, CASZ1, AL139423.1, HSPE1P24, C1orf127.
- chr1:15,807,169–16,073,651, 17 genes, copy number 8: UQCRHL, AL450998.1, FLJ37453, SPEN, AL034555.1, ZBTB17, AL355994.4, AL355994.1, AL355994.5, TBC1D3P6, SRARP, AL355994.3, HSPB7, CLCNKA, AL355994.2, CLCNKB, FAM131C.
- chr1:18,015,712–18,388,514, 6 genes, copy number 11: AL357509.1, LINC01654, IGSF21, AL365209.1, IGSF21-AS1, AL591896.1.
- chr1:44,850,522–45,750,653, 33 genes, copy number 8: EIF2B3, RNA5SP47, CCNB1IP1P1, PPIAP35, MRPS17P1, HECTD3, UROD, ZSWIM5, OSTCP5, LINC01144, HPDL, MUTYH, AL451136.1, TOE1, TESK2, PPIAP36, CCDC163, MMACHC, PRDX1, HMGB1P48, AKR1A1, AL355480.3, AL355480.1, NASP, AL355480.2, AL355480.4, CCDC17, GPBP1L1, RPS15AP10, AL604028.2, TMEM69, IPP, AL604028.1.
- chr4:62,816,826–70,085,290, 127 genes, copy number 7–24 (broad region; genes not listed).
- chr4:70,196,496–74,316,789, 69 genes, copy number 8–33 (broad region; genes not listed).
- chr6:105,273,218–105,454,062, 1 gene, copy number 27 (within-gene range 2–27): PREP.
- chr6:105,298,149–107,133,170, 31 genes, copy number 27: AL133406.1, RPL35P3, AL096794.1, LINC02836, Z97206.1, AL591518.1, RN7SKP211, PRDM1, ATG5, AL022067.1, U4, RN7SL47P, RNU6-344P, AL356859.1, CRYBG1, Y_RNA, RNA5SP211, AL109920.1, Y_RNA, RTN4IP1, RNU6-527P, QRSL1, RPL21P65, LINC02526, LINC02532, RNU6-117P, MIR587, CD24, MTRES1, BEND3, RNU6-1299P.
- chr6:107,192,300–107,192,573, 1 gene, copy number 27: AL591516.1.
- chr6:115,931,149–116,932,161, 27 genes, copy number 14–25: FRK, AL357141.1, TPI1P3, NT5DC1, COL10A1, NIP7P3, AL050331.2, TSPYL4, DSE, AL050331.1, TSPYL1, Z84488.1, CBX3P9, KRT18P22, CALHM6-AS1, CALHM6, AL445224.1, TRAPPC3L, CALHM5, CALHM4, RWDD1, RSPH4A, ZUP1, KPNA5, FAM162B, GPRC6A, RFX6.
- chr6:117,560,269–118,783,420, 12 genes, copy number 12: GOPC, NEPNP, NUS1, SLC35F1, AL450405.1, AL589993.1, CEP85L, BRD7P3, PLN, Z99496.1, SSXP10, SELENOKP3.
- chr6:119,177,205–119,391,829, 4 genes, copy number 14 (within-gene range 2–14): MAN1A1, AL022722.1, RNU6-194P, AL078600.1.
- chr6:122,399,551–122,726,373, 10 genes, copy number 19: HSF2, Z99129.4, SERINC1, Z99129.1, PKIB, Z99129.3, Z99129.2, AL512283.2, AL512283.1, AL512283.3.
- chr6:124,644,434–132,893,819, 121 genes, copy number 8–31 (within-gene range 6–31) (broad region; genes not listed).
- chr6:137,823,673–138,344,663, 9 genes, copy number 16 (within-gene range 2–16): WAKMAR2, TNFAIP3, AL591468.1, LINC02528, LINC02865, RPSAP42, PERP, ARFGEF3, PBOV1.
- chr6:139,271,362–140,205,326, 12 genes, copy number 18 (within-gene range 2–18): AL592429.2, AL592429.1, CITED2, LINC01625, ATP5PBP6, AL390205.1, FILNC1, AL050338.1, AL050338.2, AL357146.1, RNA5SP220, MIR3668.
- chr6:140,683,814–140,683,883, 1 gene, copy number 18: MIR4465.
- chr6:141,635,650–143,490,616, 26 genes, copy number 14–42 (within-gene range 2–42): RPS3AP23, NMBR, AL589674.1, NMBR-AS1, GJE1, VTA1, AL360007.1, ADGRG6, AL359313.1, AL355337.1, AL023584.1, HIVEP2, AL023584.2, AL355304.1, LINC01277, AL023581.2, AIG1, AL023581.1, AL136116.2, AL136116.1, AL136116.3, AL031320.1, ADAT2, TUBB8P2, RNA5SP221, PEX3.
- chr6:144,285,701–144,853,034, 1 gene, copy number 9 (within-gene range 6–9): UTRN.
- chr6:144,397,959–145,964,423, 15 genes, copy number 9: AL590704.1, AL513475.1, AL513475.2, AL023283.1, EPM2A, RNU1-33P, AL031119.1, AL023806.1, AL023806.2, AL023806.5, AL023806.4, AL023806.3, FBXO30, FBXO30-DT, SHPRH.
- chr6:147,508,690–149,749,665, 39 genes, copy number 7–18: SAMD5, AL033504.1, AL365271.1, AL445123.2, AL445123.1, AL359382.1, AL359382.2, AL513164.1, SASH1, RNU6-1222P, CYP51A1P3, SNRPEP6, RPSAP40, UST, UST-AS1, UST-AS2, AL603766.1, AL031056.1, TAB2, TAB2-AS1, AL031056.2, RN7SL234P, FABP12P1, SUMO4, ZC3H12D, AL031133.1, PPIL4, RNU7-3P, AL078581.3, GINM1, AL078581.4, AL078581.2, RPS18P9, AL078581.1, KATNA1, Y_RNA, LATS1, AL358852.1, NUP43.
- chr6:153,004,459–154,605,954, 26 genes, copy number 7 (within-gene range 4–7): RGS17, RNA5SP224, AL590867.1, AL590867.2, AL358134.1, RNA5SP225, MTCO2P31, AL603908.1, MTATP6P31, MTCO3P31, MTND3P20, MTND4LP20, MTND4P13, RNU6-896P, HMGB3P19, OPRM1, IPCEF1, AL357075.4, AL445220.1, CNKSR3, AL357075.2, AL357075.3, AL357075.1, MTRES1P1, RPS4XP8, AL591419.1.
- chr6:164,148,022–166,317,470, 27 genes, copy number 7–16: Z97205.3, AL139190.1, AL358972.1, AL450345.2, AL450345.1, AL133538.1, AL136100.1, C6orf118, PDE10A, RNA5SP226, RNU6-730P, AL590302.2, AL590302.1, LINC00602, GAPDHP72, AL627443.3, AL627443.1, AL627443.2, TBXT, LNCDAT, RNU6-153P, AL121956.6, AL121956.1, GNG5P1, AL121956.5, PRR18, AL121956.7.
- chr10:78,179,174–78,675,109, 2 genes, copy number 8 (within-gene range 6–8): AC012560.1, LINC00595.
- chr10:78,352,597–80,092,557, 48 genes, copy number 8: AC010163.2, SNORA71, AL583852.1, AC016820.1, ZMIZ1-AS1, AL356753.1, ZMIZ1, PPIF, ZCCHC24, AL133481.1, TPRX1P1, AL133481.3, AL133481.2, EIF5AL1, BX248123.1, RPS12P18, SFTPA2, MBL3P, SFTPA3P, SFTPA1, LINC02679, AL132656.2, NUTM2B-AS1, AL132656.3, AL132656.4, BEND3P3, AL132656.1, NUTM2B, AL135925.1, NUTM2E, NPAP1P2, CTSLP6, PGGT1BP2, AL512662.1, BMS1P21, MBL1P, SFTPD, SFTPD-AS1, ZNRF2P3, DPY19L2P5, AL356095.1, C1DP3, C1DP2, C1DP4, TMEM254-AS1, AL356095.3, TMEM254, AL356095.2.
- chr10:96,832,254–97,426,076, 15 genes, copy number 8 (within-gene range 3–8): LCOR, HMGN2P35, SLIT1, SLIT1-AS1, ARHGAP19-SLIT1, AL512424.1, ARHGAP19, AL359385.1, Metazoa_SRP, RPL12P27, FRAT1, FRAT2, AL355490.1, RRP12, RPL34P20.
- chr14:37,556,158–38,041,442, 6 genes, copy number 11 (within-gene range 3–11): AL121790.2, AL121790.1, FOXA1, TTC6, AL136296.1, RNU6-1277P.
- chr14:42,608,868–43,596,683, 10 genes, copy number 7: AL442163.2, AL442163.3, YWHAQP1, AL163153.1, TUBBP3, HNRNPUP1, AL583809.1, KRT8P2, AL358913.1, ARHGAP16P.
- chr14:50,237,563–52,156,179, 59 genes, copy number 7 (within-gene range 6–7): L2HGDH, MIR4504, DMAC2L, AL359397.2, CDKL1, AL359397.1, MAP4K5, AL118556.1, Y_RNA, AL118556.2, ATL1, SNRPGP1, SAV1, RN7SL452P, AL606834.1, ZFP64P1, NIN, AL606834.2, AL133485.2, AL133485.3, AL133485.1, AL358334.1, PYGL, ABHD12B, AL358334.3, AL358334.2, TRIM9, AL358334.4, AL591770.1, TMX1, SNORA70, Y_RNA, LINC00519, LINC00640, AL358332.1, LINC02310, SETP2, FRMD6-AS2, FRMD6, RNU6-1291P, AL122125.1, FRMD6-AS1, RNA5SP385, RNU6-301P, AL079307.2, OR7E105P, OR7E106P, AL079307.1, OR7E159P, AL079307.3, GNG2, AL358333.2, AL358333.3, AL358333.1, RTRAF, NID2, LINC02319, COX5AP2, AL118557.1.
- chr17:27,651,334–30,360,566, 163 genes, copy number 7–10 (within-gene range 4–10) (broad region; genes not listed).
- chr17:39,057,019–40,598,585, 70 genes, copy number 9–26 (within-gene range 1–26) (broad region; genes not listed).
- chr17:48,831,018–51,120,868, 118 genes, copy number 7–24 (within-gene range 3–24) (broad region; genes not listed).
- chr19:55,072,020–56,626,481, 114 genes, copy number 8–13 (broad region; genes not listed).
- chr19:56,643,159–56,657,247, 1 gene, copy number 9 (within-gene range 6–9): SMIM17.
- chr20:1,888,128–2,341,079, 12 genes, copy number 8: AL117335.1, SIRPA, PDYN-AS1, PDYN, RPL7P2, STK35, AL359916.1, AL121899.3, AL121899.4, AL121899.1, AL121899.2, TGM3.
- chr20:21,755,270–23,421,519, 33 genes, copy number 10–38: RPL41P1, AL109807.1, LINC01432, AL035258.1, LINC01427, AL049737.1, AL121912.1, AL133464.1, LINC00261, FOXA2, LNCNEF, LINC01747, AL158175.1, KRT18P3, CYB5AP4, AL353132.1, AL049651.1, AL049651.2, SSTR4, THBD, AL118508.3, CD93, LINC00656, AL118508.2, RNA5SP478, AL118508.1, AL390037.1, NXT1-AS1, NXT1, LINC01431, GZF1, NAPB, RNA5SP479.

Autosomal genes at a single copy (total copy number 1): 1,150. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
